Somatic mutation profile of tumor specimen HCM-BROD-0003-C71-86A (aliquot HCM-BROD-0003-C71-86A-01D-A78L-36) from HCMI case HCM-BROD-0003-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 82.1 years (29,995 days).
Specimen HCM-BROD-0003-C71-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47a2ed28-24fb-49f0-96ec-9d5459fb962f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0003-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0003-C71-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/751384c2-b5ee-44a2-9d56-b4ae7130e688

The open-access MAF lists 168 somatic variants for this specimen: 102 protein-altering or splice-affecting, 39 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 39, Intron 15, Nonsense Mutation 9, 3'UTR 6, 5'UTR 3, Frame Shift Del 3, RNA 2, In Frame Del 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 329/329 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS17 | c.2651G>A p.R884Q | Missense Mutation (SNP) | VAF 43/625 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs922631314, COSV51489649, COSV99170293; called by muse, mutect2
- ANHX | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 76/119 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs566321789; called by muse, mutect2, varscan2
- ANKS1B | c.2412G>T p.E804D | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs759070307; called by muse, mutect2, varscan2
- ANO1 | c.1939C>T p.R647* | Nonsense Mutation (SNP) | VAF 95/295 reads (32%) | catalogued as COSV60283632; called by muse, mutect2, varscan2
- ASS1 | c.499C>T p.H167Y | Missense Mutation (SNP) | VAF 29/605 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.552); catalogued as rs978412155; called by muse, mutect2
- C20orf194 | c.3463C>T p.R1155W | Missense Mutation (SNP) | VAF 64/221 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs377127941; called by muse, mutect2, varscan2
- CFAP43 | c.3272C>T p.P1091L | Missense Mutation (SNP) | VAF 200/200 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); catalogued as rs781153112, COSV63852972; called by muse, mutect2, varscan2
- CNGB1 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 239/376 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); catalogued as rs1474407023; called by muse, mutect2, varscan2
- CNTNAP2 | c.2197G>A p.E733K | Missense Mutation (SNP) | VAF 144/542 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs991842796, COSV62149731, COSV62236322; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPA3 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as rs374800491; called by muse, mutect2, varscan2
- DSPP | c.2529_2537del p.S847_D849del | In Frame Del (DEL) | VAF 358/624 reads (57%) | catalogued as rs1560479204; called by mutect2, varscan2
- DUSP8 | c.927C>A p.D309E | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.13); catalogued as rs1251976057, COSV59031372; called by muse, mutect2
- FRMPD2 | c.3230del p.K1077Sfs*6 | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | catalogued as COSV100563975; called by mutect2, varscan2
- FSIP2 | c.8219A>G p.K2740R | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1381462178, COSV58090217; called by muse, mutect2
- GRIK4 | c.1976T>G p.L659R | Missense Mutation (SNP) | VAF 16/428 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101483770; called by muse, mutect2
- KIAA0319 | c.2660G>A p.R887Q | Missense Mutation (SNP) | VAF 52/262 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs150777675; called by muse, mutect2, varscan2
- KIDINS220 | c.3454C>T p.P1152S | Missense Mutation (SNP) | VAF 81/125 reads (65%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1167491479; called by muse, mutect2, varscan2
- LEFTY2 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 168/609 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.183); catalogued as rs1195590424; called by muse, mutect2, varscan2
- MADCAM1 | c.929C>T p.S310L | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.788); catalogued as rs199507986; called by muse, mutect2
- MGAT1 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 128/351 reads (36%) | PolyPhen benign (0.017); catalogued as rs1206612538, COSV57134679; called by muse, mutect2, varscan2
- MINDY4 | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 107/359 reads (30%) | catalogued as rs1279694160, COSV54670818, COSV54671079; called by muse, mutect2, varscan2
- NEFM | c.870G>T p.E290D | Missense Mutation (SNP) | VAF 342/550 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.177); catalogued as rs760454116; called by muse, mutect2, varscan2
- ODAM | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs758616960; called by muse, mutect2
- OR5T2 | c.619T>A p.F207I | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57591826; called by muse, mutect2, varscan2
- PKHD1 | c.7030T>C p.F2344L | Missense Mutation (SNP) | VAF 379/380 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as rs756780930; called by muse, mutect2, varscan2
- PLCH2 | c.2770C>T p.R924W | Missense Mutation (SNP) | VAF 59/222 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1445934710; called by muse, mutect2, varscan2
- PPP6R1 | c.2170C>T p.P724S | Missense Mutation (SNP) | VAF 34/34 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs767483312; called by muse, mutect2, varscan2
- RHPN2 | c.1544G>T p.R515L | Missense Mutation (SNP) | VAF 238/239 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as rs1347761451, COSV54275765; called by muse, mutect2, varscan2
- RP1 | c.1486G>T p.D496Y | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1284126870; called by muse, mutect2, varscan2
- RUFY1 | c.1731G>A p.M577I | Missense Mutation (SNP) | VAF 138/228 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100106485; called by muse, mutect2
- SDCBP | c.776C>A p.S259* | Nonsense Mutation (SNP) | VAF 8/184 reads (4%) | catalogued as COSV99233567; called by muse, mutect2
- SELP | c.2369C>T p.T790M | Missense Mutation (SNP) | VAF 172/317 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.373); catalogued as rs75278502; called by muse, mutect2, varscan2
- SELPLG | c.1022T>G p.L341R | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57312116; called by muse, mutect2
- SNRPN | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 95/126 reads (75%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.435); catalogued as rs777253872, COSV57597975; called by muse, mutect2, varscan2
- THBS1 | c.2938C>T p.R980C | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs781417873, COSV52955157; called by muse, mutect2, varscan2
- TRIM49 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 212/890 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs141552770, COSV61672343; called by muse, mutect2, varscan2
- TRMU | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 343/344 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99324468; called by muse, mutect2, varscan2
- TTN | c.33847C>T p.R11283C (on ENST00000591111; = p.R10356C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/350 reads (21%) | PolyPhen benign (0.219); catalogued as rs1187808745, COSV100636966; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UGT2A1 | c.1461C>G p.H487Q | Missense Mutation (SNP) | VAF 66/249 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99684803; called by muse, mutect2
- UGT8 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 128/174 reads (74%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs114818124; called by muse, mutect2, varscan2
- UMOD | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 168/556 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs387907550, COSV56775644; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC5CL | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 241/241 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs1327927428; called by muse, mutect2, varscan2
- WDR31 | c.412C>A p.P138T (on ENST00000374193 / NM_001006615.3; = p.P137T on NM_145241.5) | Missense Mutation (SNP) | VAF 19/209 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.883); catalogued as COSV59145762; called by muse, mutect2
- AARS1 | c.1769G>A p.W590* | Nonsense Mutation (SNP) | VAF 111/371 reads (30%) | called by muse, mutect2, varscan2
- AL035460.1 | c.457G>T p.V153L | Missense Mutation (SNP) | VAF 67/208 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ALPK2 | c.109+1G>A p.X37_splice | Splice Site (SNP) | VAF 64/66 reads (97%) | called by muse, mutect2, varscan2
- ALPK3 | c.4445G>A p.C1482Y | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ATP11C | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 17/267 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.41); called by muse, mutect2
- ATP2B2 | c.308T>C p.L103P | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATR | c.4118C>T p.T1373I | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.14); called by muse, mutect2
- CAPN13 | c.408G>T p.W136C | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CBY2 | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- CEP76 | c.199A>T p.K67* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- CNKSR1 | c.1888C>A p.L630I (on ENST00000374253 / NM_001297647.2; = p.L623I on NM_006314.3) | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- COL4A5 | c.607A>C p.M203L | Missense Mutation (SNP) | VAF 60/630 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- CXorf65 | c.254C>T p.T85I | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2
- DDOST | c.148C>A p.L50M (on ENST00000415136; = p.L33M on NM_005216.5) | Missense Mutation (SNP) | VAF 17/344 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2
- DGKH | c.718G>C p.D240H | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- DLGAP3 | c.660C>A p.H220Q | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2
- DYNC2H1 | c.8978G>C p.G2993A | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FAM53A | c.454C>G p.P152A | Missense Mutation (SNP) | VAF 12/299 reads (4%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.02); called by muse, mutect2
- FANCM | c.722T>A p.I241N | Missense Mutation (SNP) | VAF 142/142 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- FN1 | c.1828G>C p.G610R | Missense Mutation (SNP) | VAF 80/139 reads (58%) | SIFT tolerated (0.93); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FSIP2 | c.13737C>A p.F4579L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAREM1 | c.1718C>T p.S573L | Missense Mutation (SNP) | VAF 87/91 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HCFC1 | c.2087C>A p.A696E | Missense Mutation (SNP) | VAF 24/343 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, mutect2
- IL2RG | c.116A>G p.D39G | Missense Mutation (SNP) | VAF 13/276 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.037); called by muse, mutect2
- KCNA2 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCTD19 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- KIAA1210 | c.1834T>G p.S612A | Missense Mutation (SNP) | VAF 13/298 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- LRRIQ4 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 133/209 reads (64%) | SIFT tolerated (0.31); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- MASP2 | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 9/204 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.082); called by muse, mutect2
- MAST4 | c.2167A>T p.T723S (on ENST00000403625 / NM_001164664.2; = p.T534S on NM_015183.3) | Missense Mutation (SNP) | VAF 116/188 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRPL1 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 27/105 reads (26%) | called by muse, mutect2, varscan2
- MYH7 | c.3606G>T p.E1202D | Missense Mutation (SNP) | VAF 26/509 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2
- NDUFA2 | c.237G>C p.L79F | Missense Mutation (SNP) | VAF 146/412 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NOL8 | c.1149A>T p.E383D | Missense Mutation (SNP) | VAF 84/134 reads (63%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- NUMA1 | c.6331G>A p.G2111S | Missense Mutation (SNP) | VAF 19/300 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.156); called by muse, mutect2
- OR4C3 | c.448G>T p.G150C | Missense Mutation (SNP) | VAF 78/114 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OTOGL | c.2371C>G p.L791V (on ENST00000547103; = p.L782V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 93/144 reads (65%) | SIFT tolerated (0.81); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PLXNC1 | c.3632A>G p.N1211S | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.346); called by muse, mutect2
- PTEN | c.891del p.Q298Kfs*9 | Frame Shift Del (DEL) | VAF 193/265 reads (73%) | called by mutect2, pindel, varscan2
- RASSF9 | c.878G>A p.S293N | Missense Mutation (SNP) | VAF 58/185 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- RCAN3 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 65/96 reads (68%) | called by muse, mutect2, varscan2
- RNASE7 | c.198A>C p.K66N | Missense Mutation (SNP) | VAF 26/450 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RNF2 | c.577A>G p.S193G | Missense Mutation (SNP) | VAF 23/442 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2
- RPA1 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 147/147 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SETD7 | c.1008G>A p.W336* | Nonsense Mutation (SNP) | VAF 15/255 reads (6%) | called by muse, mutect2
- SGCZ | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 14/309 reads (5%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); called by muse, mutect2
- SH2D3A | c.1295G>A p.W432* | Nonsense Mutation (SNP) | VAF 165/165 reads (100%) | called by muse, mutect2, varscan2
- SLC22A2 | c.980C>T p.T327I | Missense Mutation (SNP) | VAF 78/78 reads (100%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLCO6A1 | c.2051C>G p.T684S | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- SNX25 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 77/238 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- SRGAP2 | c.2911G>C p.V971L (on ENST00000624873 / NM_001170637.4; = p.V972L on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.406); called by muse, mutect2
- TG | c.3567G>T p.W1189C | Missense Mutation (SNP) | VAF 172/464 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TLN2 | c.2269T>A p.C757S | Missense Mutation (SNP) | VAF 15/492 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2
- TMC5 | c.415G>T p.G139C | Missense Mutation (SNP) | VAF 20/454 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.554); called by muse, mutect2
- TMTC4 | c.2121del p.K707Nfs*23 (on ENST00000376234 / NM_001350577.2; = p.K726Nfs*23 on NM_032813.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 51/135 reads (38%) | called by mutect2, pindel, varscan2
- TRIM63 | c.347A>T p.K116M | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2
- ZNF142 | c.1618C>T p.H540Y (on ENST00000411696 / NM_001379660.1; = p.H340Y on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/374 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ZNF638 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.018); called by muse, mutect2
- ABCD1 | c.1674C>T p.I558= | Silent (SNP) | VAF 348/699 reads (50%) | called by muse, mutect2, varscan2
- ADGRD1 | c.1956G>A p.V652= | Silent (SNP) | VAF 12/235 reads (5%) | catalogued as rs1450531273; called by muse, mutect2
- ADH1A | c.942C>G p.T314= | Silent (SNP) | VAF 44/221 reads (20%) | called by muse, mutect2, varscan2
- ANKRD26 | c.1626C>T p.N542= | Silent (SNP) | VAF 12/168 reads (7%) | catalogued as rs1304409742; called by muse, mutect2
- ASB10 | c.1191C>T p.V397= (on ENST00000420175 / NM_001142459.2; = p.V382= on NM_080871.4) | Silent (SNP) | VAF 63/170 reads (37%) | catalogued as rs753462958; called by muse, mutect2, varscan2
- ATP11A | c.3195G>C p.V1065= | Silent (SNP) | VAF 6/140 reads (4%) | called by muse, mutect2
- CFAP61 | c.1959C>T p.N653= | Silent (SNP) | VAF 18/52 reads (35%) | called by muse, mutect2, varscan2
- COL17A1 | c.2613C>A p.S871= | Silent (SNP) | VAF 4/76 reads (5%) | called by muse, mutect2
- COX11 | c.117G>A p.E39= | Silent (SNP) | VAF 263/576 reads (46%) | catalogued as rs950513526; called by muse, mutect2, varscan2
- FAM117A | c.552C>T p.H184= | Silent (SNP) | VAF 168/300 reads (56%) | catalogued as rs1166086388; called by muse, mutect2, varscan2
- FANCM | c.723C>A p.I241= | Silent (SNP) | VAF 141/141 reads (100%) | called by muse, mutect2, varscan2
- FLNB | c.879T>C p.V293= | Silent (SNP) | VAF 22/388 reads (6%) | called by muse, mutect2
- GGA1 | c.1275C>T p.L425= | Silent (SNP) | VAF 20/186 reads (11%) | catalogued as rs1361033093; called by muse, mutect2, varscan2
- ITGAD | c.918G>A p.A306= | Silent (SNP) | VAF 65/193 reads (34%) | catalogued as rs141660381; called by muse, mutect2, varscan2
- ITGAE | c.2946G>C p.G982= | Silent (SNP) | VAF 16/246 reads (7%) | called by muse, mutect2
- KANK3 | c.963G>A p.E321= | Silent (SNP) | VAF 196/197 reads (99%) | called by muse, mutect2, varscan2
- KIF2B | c.171G>A p.T57= | Silent (SNP) | VAF 26/574 reads (5%) | catalogued as rs768946124, COSV99276062; called by muse, mutect2
- LCK | c.213C>T p.S71= | Silent (SNP) | VAF 114/177 reads (64%) | called by muse, mutect2, varscan2
- LILRB1 | c.1482C>T p.L494= | Silent (SNP) | VAF 168/177 reads (95%) | catalogued as rs1466196752; called by muse, mutect2, varscan2
- MYH11 | c.4674G>A p.T1558= | Silent (SNP) | VAF 26/762 reads (3%) | catalogued as rs778499852; ClinVar: likely benign; called by muse, mutect2
- NDC80 | c.936A>G p.A312= | Silent (SNP) | VAF 45/45 reads (100%) | called by muse, mutect2, varscan2
- NPTX2 | c.1038C>T p.P346= | Silent (SNP) | VAF 120/175 reads (69%) | catalogued as rs187478353, COSV99675129; called by muse, mutect2, varscan2
- NYAP2 | c.117G>A p.A39= | Silent (SNP) | VAF 65/304 reads (21%) | catalogued as rs916212363, COSV56014602; called by muse, mutect2
- OR2T33 | c.57C>G p.T19= | Silent (SNP) | VAF 8/155 reads (5%) | called by muse, mutect2
- OR5AU1 | c.123G>T p.G41= | Silent (SNP) | VAF 31/320 reads (10%) | called by muse, mutect2
- OR6K3 | c.270C>T p.T90= (on ENST00000368146; = p.T74= on NM_001005327.2) | Silent (SNP) | VAF 7/163 reads (4%) | called by muse, mutect2
- PLSCR4 | c.753A>C p.S251= | Silent (SNP) | VAF 30/222 reads (14%) | called by muse, mutect2, varscan2
- POM121L12 | c.267G>A p.P89= | Silent (SNP) | VAF 84/265 reads (32%) | catalogued as rs772385441, COSV101374858, COSV68692323; called by muse, mutect2, varscan2
- RBMXL3 | c.441C>A p.P147= | Silent (SNP) | VAF 119/254 reads (47%) | called by muse, mutect2, varscan2
- RINT1 | c.186G>A p.K62= | Silent (SNP) | VAF 76/137 reads (55%) | catalogued as COSV57557752; called by muse, mutect2, varscan2
- RPAP2 | c.18G>C p.G6= | Silent (SNP) | VAF 16/166 reads (10%) | called by muse, mutect2
- SEPTIN8 | c.300C>G p.T100= | Silent (SNP) | VAF 7/174 reads (4%) | catalogued as COSV99736547; called by muse, mutect2
- SFMBT2 | c.945T>C p.F315= | Silent (SNP) | VAF 8/199 reads (4%) | called by muse, mutect2
- TENM3 | c.7353C>T p.F2451= | Silent (SNP) | VAF 71/308 reads (23%) | catalogued as rs1414793363; called by muse, mutect2, varscan2
- TMEM132C | c.504A>G p.P168= | Silent (SNP) | VAF 193/333 reads (58%) | catalogued as rs761907910; called by muse, mutect2, varscan2
- TRABD2B | c.756C>A p.I252= | Silent (SNP) | VAF 105/317 reads (33%) | called by muse, mutect2, varscan2
- WWP2 | c.666C>T p.V222= | Silent (SNP) | VAF 147/251 reads (59%) | catalogued as rs1217318959; called by muse, mutect2, varscan2
- ZIC2 | c.309G>T p.A103= | Silent (SNP) | VAF 105/228 reads (46%) | called by muse, mutect2, varscan2
- ZNF674 | c.24G>A p.L8= | Silent (SNP) | VAF 195/451 reads (43%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-9179T>A | Intron (SNP) | VAF 47/914 reads (5%) | called by muse, mutect2
- ATPAF1 | c.267-294A>G | Intron (SNP) | VAF 11/218 reads (5%) | called by muse, mutect2
- CELF4 | c.1165+35A>G | Intron (SNP) | VAF 89/91 reads (98%) | called by muse, mutect2, varscan2
- COX20 | c.*40A>G | 3'UTR (SNP) | VAF 10/168 reads (6%) | called by muse, mutect2
- DCC | c.3163+152G>A | Intron (SNP) | VAF 43/44 reads (98%) | catalogued as rs1027237408; called by muse, mutect2, varscan2
- EIF4G1 | c.4260+30C>G | Intron (SNP) | VAF 24/638 reads (4%) | called by muse, mutect2
- EPB41L4A | chr5:112420322 G>C | 5'Flank (SNP) | VAF 24/142 reads (17%) | called by muse, mutect2, varscan2
- FCRL5 | c.307+727C>G | Intron (SNP) | VAF 15/192 reads (8%) | called by muse, mutect2
- FRMPD2B | n.647del | RNA (DEL) | VAF 44/126 reads (35%) | called by mutect2, varscan2
- GABRE | c.784+1301G>T | Intron (SNP) | VAF 159/365 reads (44%) | called by muse, mutect2, varscan2
- IRF5 | c.195+842C>T | Intron (SNP) | VAF 27/79 reads (34%) | catalogued as rs1269749804; called by muse, mutect2, varscan2
- ITGA3 | c.*97G>A | 3'UTR (SNP) | VAF 13/326 reads (4%) | called by muse, mutect2
- LMX1B | c.*41G>T | 3'UTR (SNP) | VAF 89/226 reads (39%) | called by muse, mutect2, varscan2
- LTO1 | c.50+97G>A | Intron (SNP) | VAF 25/150 reads (17%) | called by muse, mutect2, varscan2
- MAX | c.172-6220G>A | Intron (SNP) | VAF 231/233 reads (99%) | catalogued as rs188440951; called by muse, mutect2, varscan2
- MGAT5B | c.1025+7507G>A | Intron (SNP) | VAF 72/148 reads (49%) | called by muse, mutect2, varscan2
- NAT8L | c.*25C>T | 3'UTR (SNP) | VAF 27/97 reads (28%) | called by muse, mutect2, varscan2
- PALB2 | c.2834+24T>C | Intron (SNP) | VAF 130/193 reads (67%) | called by muse, mutect2, varscan2
- PHYKPL | c.60-258G>T | Intron (SNP) | VAF 15/389 reads (4%) | called by muse, mutect2
- PIP5K1B | c.*37G>A | 3'UTR (SNP) | VAF 69/150 reads (46%) | catalogued as rs771826277, COSV99598505; called by muse, mutect2, varscan2
- RPGR | c.2520+1187del | Intron (DEL) | VAF 68/169 reads (40%) | catalogued as rs1186795749, CD033277; called by mutect2, pindel, varscan2
- RPS26P15 | n.150C>A | RNA (SNP) | VAF 142/518 reads (27%) | called by muse, mutect2, varscan2
- SMARCA1 | c.2329-9C>A | Intron (SNP) | VAF 49/131 reads (37%) | called by muse, mutect2, varscan2
- TFB1M | c.-25G>A | 5'UTR (SNP) | VAF 391/393 reads (99%) | catalogued as rs931406879; called by muse, mutect2, varscan2
- TPP2 | c.-8C>G | 5'UTR (SNP) | VAF 17/198 reads (9%) | called by muse, mutect2
- VAPB | c.*5165G>A | 3'UTR (SNP) | VAF 25/129 reads (19%) | catalogued as rs1450622752; called by muse, mutect2, varscan2
- ZNF611 | c.-12T>G | 5'UTR (SNP) | VAF 11/101 reads (11%) | called by muse, mutect2, varscan2
